Somatic mutation profile of tumor specimen TCGA-IQ-A61K-01A (aliquot TCGA-IQ-A61K-01A-11D-A30E-08) from TCGA case TCGA-IQ-A61K, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 70.4 years (25,697 days).
Specimen TCGA-IQ-A61K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23569460-174f-4372-9a01-e75541d1789c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IQ-A61K-10A (Blood Derived Normal), aliquot TCGA-IQ-A61K-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8cd66495-43f4-4183-a904-9b710bd984ce

The open-access MAF lists 77 somatic variants for this specimen: 56 protein-altering or splice-affecting, 20 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 20, Nonsense Mutation 4, Splice Site 2, Frame Shift Del 1, In Frame Del 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RAG2 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762407838, CM108347, COSV100271510; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 49/78 reads (63%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAMTS20 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143824237; called by mutect2, varscan2
- B4GALNT4 | c.2329G>A p.V777I | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.27); catalogued as rs1471372704, COSV100327882; called by muse, mutect2
- CBLIF | c.8G>A p.W3* | Nonsense Mutation (SNP) | VAF 27/180 reads (15%) | catalogued as COSV99951095; called by muse, mutect2, varscan2
- CHST12 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 33/163 reads (20%) | catalogued as COSV99324689; called by muse, mutect2, varscan2
- CLK2 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs767100429, COSV100751935; called by muse, mutect2, varscan2
- COIL | c.819G>T p.E273D | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.189); catalogued as COSV99538406; called by muse, mutect2, varscan2
- CTNNA2 | c.1074A>T p.K358N | Missense Mutation (SNP) | VAF 15/326 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.348); catalogued as COSV100562097; called by muse, mutect2
- FABP12 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.483); catalogued as rs777011733, COSV64616709; called by muse, mutect2
- FHL1 | c.142G>A p.G48S | Missense Mutation (SNP) | VAF 68/355 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.264); catalogued as COSV61780230, COSV61780414; called by muse, mutect2, varscan2
- FTCD | c.508A>C p.S170R | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.76); PolyPhen benign (0.073); catalogued as COSV99385481; called by muse, mutect2, varscan2
- GABRE | c.581G>C p.G194A | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.817); catalogued as COSV100944390, COSV64819117; called by muse, mutect2, varscan2
- GIMAP5 | c.880A>G p.I294V | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs368122062; called by muse, mutect2, varscan2
- HEATR5A | c.3632G>A p.R1211H | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1193337792, COSV101120577; called by muse, mutect2, varscan2
- HEG1 | c.3155C>T p.P1052L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.809); catalogued as rs200205505, COSV100230717; called by muse, mutect2, varscan2
- INSYN2A | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.371); catalogued as rs143223796; called by muse, mutect2, varscan2
- KCNJ11 | c.644T>C p.I215T | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100379228; called by muse, mutect2, varscan2
- KIAA1109 | c.14231G>A p.R4744H | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.91); catalogued as COSV52668778; called by muse, mutect2, varscan2
- KLK6 | c.436A>G p.T146A | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as COSV100037854; called by muse, mutect2, varscan2
- KRT72 | c.772A>G p.K258E | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.12); catalogued as rs778749490, COSV99537512; called by muse, mutect2, varscan2
- LARGE1 | c.538C>T p.Q180* | Nonsense Mutation (SNP) | VAF 26/90 reads (29%) | catalogued as COSV100506395; called by muse, mutect2, varscan2
- LGALS12 | c.518A>G p.Y173C | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.707); catalogued as COSV99737382; called by muse, mutect2, varscan2
- LMTK2 | c.4247G>A p.G1416D | Missense Mutation (SNP) | VAF 80/256 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99807823; called by muse, mutect2, varscan2
- LRP1B | c.3490C>T p.P1164S | Missense Mutation (SNP) | VAF 46/238 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV101261418; called by muse, mutect2, varscan2
- MAEL | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.152); catalogued as rs773190752, COSV63305334; called by muse, mutect2, varscan2
- MAP3K20 | c.1396G>A p.D466N | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV100919640; called by muse, mutect2, varscan2
- NAA11 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as rs781256858, COSV99727331; called by muse, mutect2, varscan2
- NBAS | c.208A>G p.S70G | Missense Mutation (SNP) | VAF 55/69 reads (80%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as rs771231640, COSV99869881, COSV99871686; called by muse, mutect2, varscan2
- NOS1 | c.316C>T p.H106Y | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.486); catalogued as COSV100501463; called by muse, mutect2, varscan2
- OR2AG2 | c.692A>G p.N231S | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.038); catalogued as COSV100643182; called by muse, mutect2, varscan2
- OR2Z1 | c.95C>A p.A32D | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.434); catalogued as COSV100136539, COSV60691866; called by muse, mutect2, varscan2
- PCDHGB5 | c.1619C>T p.A540V | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV53981242; called by muse, mutect2, varscan2
- PCLO | c.13130C>A p.A4377E | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100438109; called by muse, mutect2, varscan2
- PHF3 | c.2251C>T p.L751F | Missense Mutation (SNP) | VAF 39/196 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100014031; called by muse, mutect2, varscan2
- PPARGC1A | c.2030G>A p.R677H | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs539338812, COSV53524913; called by muse, mutect2, varscan2
- RECK | c.2668G>A p.V890I | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); catalogued as rs968106629, COSV65035438; called by muse, mutect2, varscan2
- RGS22 | c.3374G>T p.G1125V | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as COSV62658159; called by muse, mutect2, varscan2
- SCMH1 | c.1157G>A p.G386E (on ENST00000326197 / NM_001031694.2; = p.G339E on NM_012236.4) | Missense Mutation (SNP) | VAF 44/226 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100401369; called by muse, mutect2, varscan2
- SDCCAG8 | c.501A>C p.Q167H | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.646); catalogued as COSV100654662; called by muse, mutect2, varscan2
- SLC35F1 | c.655G>A p.G219R | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100838197; called by muse, mutect2, varscan2
- SLFN13 | c.709T>G p.F237V | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99540422; called by muse, mutect2, varscan2
- SPTBN5 | c.10553G>A p.G3518E | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.056); catalogued as rs1246623868, COSV100312232; called by muse, mutect2, varscan2
- TARS2 | c.173C>G p.P58R | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1233096999, COSV100946120, COSV64695203; called by muse, mutect2, varscan2
- TRAM1 | c.961C>T p.R321* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as COSV99140747; called by muse, mutect2, varscan2
- VPS13D | c.9370G>A p.E3124K | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99169561; called by muse, mutect2, varscan2
- ZBTB22 | c.1739C>T p.T580I | Missense Mutation (SNP) | VAF 44/63 reads (70%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV99802696; called by muse, mutect2, varscan2
- ZHX3 | c.1670C>T p.A557V | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs746604366, COSV100476774; called by muse, mutect2, varscan2
- ZNF610 | c.470A>G p.H157R | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100017030; called by muse, mutect2, varscan2
- ZNF792 | c.305G>A p.G102D | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101289764; called by muse, mutect2, varscan2
- CELA3A | c.715G>T p.V239F | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2
- COL7A1 | c.345_348dup p.T117Qfs*13 | Frame Shift Ins (INS) | VAF 25/112 reads (22%) | called by mutect2, pindel, varscan2
- HDGF | c.376_378del p.K126del | In Frame Del (DEL) | VAF 106/550 reads (19%) | called by pindel, varscan2
- HSD3B1 | c.1029_1030del p.Y344Qfs*32 | Frame Shift Del (DEL) | VAF 17/111 reads (15%) | called by pindel, varscan2
- MYCBP2 | c.2929_2943+18del p.X977_splice (on ENST00000357337; = p.X1015_splice on NM_015057.5) | Splice Site (DEL) | VAF 10/98 reads (10%) | called by mutect2, pindel
- SPAG1 | c.300+6_300+7dup p.X100_splice | Splice Site (INS) | VAF 15/55 reads (27%) | called by mutect2, pindel, varscan2
- ACSS3 | c.591C>G p.L197= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV99699491; called by muse, mutect2, varscan2
- AGAP2 | c.2352C>T p.S784= (on ENST00000547588 / NM_001122772.2; = p.S448= on NM_014770.4) | Silent (SNP) | VAF 38/187 reads (20%) | catalogued as COSV99224320; called by muse, mutect2, varscan2
- AL592490.1 | c.249C>A p.G83= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV101308291; called by muse, mutect2, varscan2
- CD300E | c.168G>A p.T56= | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as rs758743081, COSV60790759; called by muse, mutect2, varscan2
- GAS2L3 | c.921G>A p.S307= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as rs749864541, COSV99903181; called by muse, mutect2, varscan2
- GPCPD1 | c.1833A>C p.I611= | Silent (SNP) | VAF 29/205 reads (14%) | catalogued as COSV100980257; called by muse, mutect2, varscan2
- LUZP1 | c.2385C>T p.S795= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV100035480; called by muse, mutect2, varscan2
- MUC5B | c.7911C>A p.T2637= | Silent (SNP) | VAF 55/147 reads (37%) | catalogued as COSV101500805, COSV71593188; called by muse, mutect2, varscan2
- OR6B2 | c.144C>T p.I48= | Silent (SNP) | VAF 66/160 reads (41%) | catalogued as rs142836659, COSV53154275; called by muse, mutect2, varscan2
- PCDHA9 | c.1383G>A p.T461= | Silent (SNP) | VAF 43/196 reads (22%) | catalogued as rs558218817, COSV100969935, COSV100970128; called by muse, mutect2, varscan2
- PCDHGB1 | c.1704C>T p.S568= | Silent (SNP) | VAF 19/119 reads (16%) | catalogued as rs1422191301, COSV99547446; called by muse, mutect2, varscan2
- PSG7 | c.1083G>A p.P361= | Silent (SNP) | VAF 63/387 reads (16%) | catalogued as rs377390259; called by muse, mutect2, varscan2
- RYR1 | c.3375G>A p.G1125= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as COSV62112804; called by muse, mutect2, varscan2
- SIPA1 | c.903G>A p.P301= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs930572284, COSV67746600; called by muse, mutect2, varscan2
- SLIT2 | c.3999T>C p.C1333= | Silent (SNP) | VAF 18/105 reads (17%) | catalogued as COSV99887520; called by muse, mutect2, varscan2
- SMAD5 | c.903T>C p.D301= | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as COSV101548145; called by muse, mutect2, varscan2
- TGFBRAP1 | c.759G>A p.A253= | Silent (SNP) | VAF 22/103 reads (21%) | catalogued as rs200664212, COSV99305558; called by muse, mutect2, varscan2
- USP9X | c.7242G>A p.K2414= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV100200130; called by muse, varscan2
- VN1R2 | c.894C>A p.I298= | Silent (SNP) | VAF 75/174 reads (43%) | catalogued as rs143089101; called by muse, mutect2, varscan2
- ZNF512B | c.36C>T p.L12= | Silent (SNP) | VAF 61/150 reads (41%) | catalogued as COSV53874204, COSV53877749; called by muse, mutect2, varscan2
- OR52A4P | chr11:5120766 G>T | 3'Flank (SNP) | VAF 15/97 reads (15%) | called by muse, mutect2, varscan2
